Somatic mutation profile of tumor specimen HCM-CSHL-0384-D37-86A (aliquot HCM-CSHL-0384-D37-86A-01D-A937-36) from HCMI case HCM-CSHL-0384-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 51.4 years (18,759 days).
Specimen HCM-CSHL-0384-D37-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7f07927-1e7a-4bd9-aba1-0ed7f239be97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0384-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0384-D37-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21a4a95c-a95c-4d14-8ca9-188c248679b5

The open-access MAF lists 136 somatic variants for this specimen: 96 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 36, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 3, Intron 2, 3'UTR 1, Splice Region 1, 5'Flank 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 213/482 reads (44%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCTD7 | c.591C>T p.C197= (on ENST00000275532; = p.R211* on NM_153033.5) | Silent (SNP) | VAF 139/647 reads (21%) | catalogued as rs750811871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 262/428 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMBN | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329082409; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 145/373 reads (39%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- ARC | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 258/543 reads (48%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs780927796; called by muse, mutect2, varscan2
- ARHGEF40 | c.4459dup p.H1487Pfs*28 | Frame Shift Ins (INS) | VAF 62/268 reads (23%) | catalogued as rs758492903; called by mutect2, varscan2
- ATP8A2 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 149/229 reads (65%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs747985877, COSV54937479; called by muse, mutect2, varscan2
- BCORL1 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 387/387 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs143864671, COSV54391257; called by muse, mutect2, varscan2
- BEND4 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as rs1259529227; called by muse, mutect2, varscan2
- C8A | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 56/515 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV63486227; called by muse, mutect2, varscan2
- CCDC172 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 243/372 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781038484, COSV60937835; called by muse, mutect2, varscan2
- CCDC175 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs199964220; called by muse, mutect2, varscan2
- CELSR3 | c.7336G>A p.V2446M | Missense Mutation (SNP) | VAF 147/363 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759534857, COSV99375101; called by muse, mutect2, varscan2
- CHRNB2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 273/536 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1415028557; called by muse, mutect2, varscan2
- CLSTN3 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs764251763; called by muse, mutect2, varscan2
- CNTFR | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs368522550; called by muse, mutect2, varscan2
- COL6A3 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 258/372 reads (69%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs575412915, COSV55101444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.8765G>A p.R2922H | Missense Mutation (SNP) | VAF 197/453 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148539877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK8 | c.4249G>A p.A1417T | Missense Mutation (SNP) | VAF 136/269 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as rs1199786455; called by muse, mutect2, varscan2
- DSEL | c.968G>T p.W323L | Missense Mutation (SNP) | VAF 258/409 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100025713; called by muse, mutect2, varscan2
- EIF5B | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 162/254 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs751828370, COSV99177199; called by muse, mutect2, varscan2
- ERG | c.1121G>A p.R374H (on ENST00000398919 / NM_001243428.1; = p.R350H on NM_004449.4) | Missense Mutation (SNP) | VAF 199/390 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728243, COSV55731950; called by muse, mutect2, varscan2
- FERMT2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 164/310 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58408179; called by muse, mutect2, varscan2
- FLOT2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 138/240 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763357953, COSV67528995; called by muse, mutect2, varscan2
- GALNT12 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 153/382 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.75); catalogued as rs1256927785, COSV66662155; called by muse, mutect2, varscan2
- GHRHR | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 208/289 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754386566; called by muse, mutect2, varscan2
- GRAMD1B | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 176/269 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs780877280, COSV59205493; called by muse, mutect2, varscan2
- IRX4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 336/741 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770961282, COSV51474480, COSV51475669; called by muse, varscan2
- KCNA3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 284/554 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63901929; called by mutect2, varscan2
- LAMB4 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 126/454 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs747592570, COSV52730857; called by muse, mutect2, varscan2
- MAN2A2 | c.24_25del p.C10Wfs*45 | Frame Shift Del (DEL) | VAF 59/246 reads (24%) | catalogued as rs768881302; called by mutect2, pindel, varscan2
- MIPEP | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 199/368 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66301081; called by muse, mutect2, varscan2
- MMP15 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 186/438 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs1037153021; called by muse, mutect2, varscan2
- MRC1 | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 128/376 reads (34%) | catalogued as rs782352494; called by muse, mutect2, varscan2
- MYO15A | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 150/395 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.108); catalogued as rs1020210171; called by muse, mutect2, varscan2
- NLRP1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 266/407 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as rs200012608; called by muse, mutect2, varscan2
- OR2T4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 377/763 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs756078095, COSV63544824; called by muse, mutect2, varscan2
- PCDH15 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455035148, COSV57321053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA5 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 211/421 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1554128615, COSV65350931; called by muse, mutect2, varscan2
- PDE10A | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 108/402 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866168774, COSV63092169; called by muse, mutect2
- PIK3CG | c.2657C>T p.T886M | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV63249761; called by muse, mutect2, varscan2
- PLEC | c.11833G>A p.G3945S (on ENST00000322810 / NM_201380.4; = p.G3835S on NM_000445.5) | Missense Mutation (SNP) | VAF 306/601 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM151763; called by muse, mutect2, varscan2
- PSME4 | c.2918G>A p.R973H | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs763188055; called by muse, mutect2, varscan2
- PTCHD4 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs371181867; called by muse, mutect2, varscan2
- RAPSN | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs759579462; called by muse, mutect2, varscan2
- RSAD2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 216/337 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201120739; called by muse, mutect2, varscan2
- SLC13A5 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 301/413 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs201674669, COSV53421201; called by muse, mutect2, varscan2
- SLC24A2 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418543934, COSV53863537; called by muse, mutect2
- SLFN12 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as rs143225670; called by muse, mutect2, varscan2
- SOX11 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 249/376 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs750131174; called by muse, varscan2
- STX10 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 143/384 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.307); catalogued as rs751947745, COSV52834013; called by muse, mutect2, varscan2
- TJP1 | c.3235C>T p.R1079* | Nonsense Mutation (SNP) | VAF 218/341 reads (64%) | catalogued as COSV62043997; called by muse, varscan2
- TOR4A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 341/621 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs756370946; called by muse, mutect2, varscan2
- TRIM7 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 399/742 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs772954194; called by muse, mutect2, varscan2
- TTN | c.5774T>G p.V1925G (on ENST00000591111; = p.V1879G on NM_003319.4) | Missense Mutation (SNP) | VAF 114/375 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV100593866; called by muse, mutect2, varscan2
- TULP4 | c.2920G>T p.A974S | Missense Mutation (SNP) | VAF 175/628 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV65577334; called by muse, mutect2, varscan2
- ZC3H4 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 187/539 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756950439, COSV53410194; called by muse, mutect2, varscan2
- ZNF804A | c.2852del p.P951Lfs*34 | Frame Shift Del (DEL) | VAF 166/326 reads (51%) | catalogued as COSV56435462; called by mutect2, pindel, varscan2
- ALPP | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 302/981 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ANKRD20A1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | called by mutect2, varscan2
- ARHGEF4 | c.1792C>A p.L598I | Missense Mutation (SNP) | VAF 287/438 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by mutect2, varscan2
- BASP1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 366/684 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRF1 | c.1935G>C p.E645D | Missense Mutation (SNP) | VAF 191/325 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPSF6 | c.720_749del p.L241_P250del | In Frame Del (DEL) | VAF 145/382 reads (38%) | called by mutect2, varscan2
- CSMD3 | c.2229T>A p.N743K (on ENST00000297405 / NM_001363185.1; = p.N639K on NM_052900.3) | Missense Mutation (SNP) | VAF 170/383 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- D2HGDH | c.855C>A p.G285= | Splice Region (SNP) | VAF 82/231 reads (35%) | called by muse, mutect2, varscan2
- DAW1 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 95/182 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2
- DYNC2H1 | c.2641G>T p.D881Y | Missense Mutation (SNP) | VAF 123/200 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ETV4 | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 202/323 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FBXL4 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- GIPC3 | c.3124G>A p.G1042R | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HELLS | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 221/443 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INKA1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 214/407 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JMJD1C | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 225/337 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KIF17 | c.2531T>G p.L844W | Missense Mutation (SNP) | VAF 232/233 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT72 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 338/706 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MMRN1 | c.2875C>A p.L959I | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- MYH4 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- NDNF | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 215/346 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NKAIN4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 209/459 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR6C65 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PAPPA2 | c.3128_3135del p.P1043Lfs*49 | Frame Shift Del (DEL) | VAF 138/363 reads (38%) | called by mutect2, pindel, varscan2
- PDLIM1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 210/311 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PKHD1 | c.4825G>T p.D1609Y | Missense Mutation (SNP) | VAF 125/458 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PSMB1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 75/283 reads (27%) | called by muse, mutect2, varscan2
- PVR | c.1177A>T p.N393Y | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RFNG | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RORB | c.828G>C p.Q276H (on ENST00000396204 / NM_001365023.1; = p.Q265H on NM_006914.4) | Missense Mutation (SNP) | VAF 151/352 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TCF7L2 | c.979_983dup p.G329Mfs*24 (on ENST00000355995 / NM_001367943.1; = p.G306Mfs*24 on NM_030756.5) | Frame Shift Ins (INS) | VAF 89/359 reads (25%) | called by mutect2, varscan2
- TEX13C | c.2257C>G p.L753V | Missense Mutation (SNP) | VAF 259/288 reads (90%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TMCO5A | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZBTB4 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 250/411 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZMYM4 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 193/389 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF598 | c.1957_1973del p.L653Vfs*62 | Frame Shift Del (DEL) | VAF 182/430 reads (42%) | called by mutect2, varscan2
- ADGRE2 | c.2319C>T p.F773= | Silent (SNP) | VAF 82/363 reads (23%) | called by muse, mutect2, varscan2
- ADGRE2 | c.276C>T p.Y92= | Silent (SNP) | VAF 336/576 reads (58%) | catalogued as rs376023757; called by muse, mutect2, varscan2
- ADRB3 | c.507G>A p.S169= | Silent (SNP) | VAF 149/619 reads (24%) | called by muse, mutect2, varscan2
- ANKRD20A1 | c.546G>C p.V182= | Silent (SNP) | VAF 53/366 reads (14%) | called by muse, varscan2
- ANKRD20A4P | c.546G>C p.V182= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- ASTN2 | c.2952A>T p.P984= (on ENST00000313400 / NM_001365069.1; = p.P933= on NM_014010.5) | Silent (SNP) | VAF 191/454 reads (42%) | called by muse, mutect2, varscan2
- BCAM | c.846C>T p.R282= | Silent (SNP) | VAF 204/644 reads (32%) | catalogued as rs771831123, COSV54302776; called by muse, mutect2, varscan2
- BMP7 | c.30G>A p.A10= | Silent (SNP) | VAF 280/508 reads (55%) | called by muse, varscan2
- C2CD6 | c.150G>T p.S50= | Silent (SNP) | VAF 237/382 reads (62%) | called by muse, mutect2, varscan2
- CFAP54 | c.6606T>C p.F2202= | Silent (SNP) | VAF 221/459 reads (48%) | called by muse, mutect2, varscan2
- DGCR8 | c.2280C>T p.S760= | Silent (SNP) | VAF 225/336 reads (67%) | catalogued as rs374499450; called by muse, mutect2, varscan2
- DOK2 | c.207C>T p.A69= | Silent (SNP) | VAF 349/692 reads (50%) | catalogued as rs757512119; called by muse, mutect2, varscan2
- EVC | c.885C>G p.T295= | Silent (SNP) | VAF 115/317 reads (36%) | catalogued as COSV53836531; called by muse, mutect2, varscan2
- F2 | c.1830G>A p.K610= | Silent (SNP) | VAF 107/294 reads (36%) | called by muse, mutect2, varscan2
- FAT2 | c.4516C>T p.L1506= | Silent (SNP) | VAF 274/585 reads (47%) | called by muse, mutect2, varscan2
- FBXO40 | c.1338C>T p.D446= | Silent (SNP) | VAF 216/399 reads (54%) | catalogued as rs764170628; called by muse, mutect2, varscan2
- FOXG1 | c.246G>A p.P82= | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, varscan2
- GATA3 | c.1257C>A p.P419= | Silent (SNP) | VAF 333/480 reads (69%) | catalogued as rs768238506; called by muse, mutect2, varscan2
- GPR180 | c.264T>G p.G88= | Silent (SNP) | VAF 231/419 reads (55%) | called by muse, mutect2, varscan2
- HIVEP3 | c.6252G>A p.A2084= | Silent (SNP) | VAF 60/561 reads (11%) | catalogued as rs1417464430; called by muse, mutect2, varscan2
- PCDHB10 | c.1620G>A p.A540= | Silent (SNP) | VAF 291/515 reads (57%) | catalogued as rs17844581; called by muse, mutect2, varscan2
- PCDHB7 | c.1620G>A p.A540= | Silent (SNP) | VAF 62/1402 reads (4%) | catalogued as COSV50754071; called by muse, mutect2
- PCDHB8 | c.567C>T p.G189= | Silent (SNP) | VAF 215/400 reads (54%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.1623C>T p.S541= | Silent (SNP) | VAF 223/483 reads (46%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.795C>T p.T265= | Silent (SNP) | VAF 273/511 reads (53%) | catalogued as COSV54046688; called by muse, mutect2, varscan2
- PCDHGA6 | c.1869G>A p.T623= | Silent (SNP) | VAF 341/831 reads (41%) | catalogued as rs1032808913; called by muse, mutect2, varscan2
- PPP1R2B | c.84G>A p.S28= | Silent (SNP) | VAF 206/528 reads (39%) | catalogued as rs778681228, COSV70372913; called by muse, mutect2, varscan2
- PRKCSH | c.1365C>T p.P455= | Silent (SNP) | VAF 144/397 reads (36%) | catalogued as rs368834600; called by muse, mutect2, varscan2
- RGS6 | c.1011C>T p.F337= | Silent (SNP) | VAF 83/230 reads (36%) | catalogued as rs748015727; called by muse, mutect2, varscan2
- RNFT2 | c.186C>A p.G62= | Silent (SNP) | VAF 265/577 reads (46%) | called by muse, mutect2, varscan2
- SETBP1 | c.996C>A p.G332= | Silent (SNP) | VAF 161/274 reads (59%) | called by muse, mutect2, varscan2
- SPICE1 | c.132A>C p.A44= | Silent (SNP) | VAF 37/295 reads (13%) | called by muse, mutect2, varscan2
- TMEM175 | c.42G>A p.P14= | Silent (SNP) | VAF 278/415 reads (67%) | catalogued as rs747420455, COSV53279605; called by muse, mutect2, varscan2
- TRBV19 | c.144C>T p.H48= | Silent (SNP) | VAF 242/356 reads (68%) | catalogued as rs17263; called by muse, mutect2, varscan2
- XPO5 | c.2334G>A p.A778= | Silent (SNP) | VAF 70/244 reads (29%) | catalogued as rs745435024, COSV54827894; called by muse, mutect2, varscan2
- DOCK8 | c.53+342G>A | Intron (SNP) | VAF 109/340 reads (32%) | catalogued as rs201097337, COSV101213736, COSV66688303; called by muse, mutect2, varscan2
- KCNK12 | c.*8500C>A | 3'UTR (SNP) | VAF 190/309 reads (61%) | catalogued as COSV100010031; called by muse, varscan2
- NRG1 | chr8:31640044 C>T | 5'Flank (SNP) | VAF 128/238 reads (54%) | called by muse, mutect2, varscan2
- VIPR2 | c.152-7447A>T | Intron (SNP) | VAF 226/339 reads (67%) | called by muse, mutect2, varscan2
